Somatic mutation profile of tumor specimen TCGA-HC-7081-01A (aliquot TCGA-HC-7081-01A-11D-1961-08) from TCGA case TCGA-HC-7081, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland.
Specimen TCGA-HC-7081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82fe132d-cbf3-4dd6-bd89-86ee0dd93bf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7081-10A (Blood Derived Normal), aliquot TCGA-HC-7081-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15eecf6c-e790-408d-be56-4182db54f13e

The open-access MAF lists 26 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 19, Silent 3, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HMBS | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974712040, CM002609, COSV53828002; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1625A>C p.E542A | Missense Mutation (SNP) | VAF 6/69 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R2 | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 14/113 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372272045, COSV55846581, COSV55847676; called by muse, mutect2, varscan2
- BTLA | c.187T>C p.C63R | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57937867; called by muse, mutect2, varscan2
- CACNA1E | c.3691G>A p.V1231I | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.806); catalogued as rs376915340, COSV62403340; called by muse, mutect2, varscan2
- CCNL2 | c.795G>C p.L265F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68766412; called by muse, mutect2, varscan2
- CEP170B | c.3599G>A p.S1200N (on ENST00000453495; = p.S1129N on NM_015005.3) | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs984983700, COSV69023846; called by muse, mutect2
- COL1A2 | c.595-1G>A p.X199_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | catalogued as COSV51955514, COSV99798958; called by muse, mutect2, varscan2
- CYB5R4 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV63750515; called by muse, mutect2, varscan2
- DLL3 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs141671275; called by muse, mutect2, varscan2
- HDAC9 | c.2869G>T p.D957Y | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs866142619, COSV67770320; called by muse, mutect2
- HNRNPCL1 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs374398056; called by mutect2, varscan2
- IFT172 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV53131688; called by muse, mutect2
- KRIT1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60667347; called by muse, mutect2
- MTTP | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs755219735, COSV55504845; called by muse, mutect2, varscan2
- NLRP4 | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.84); catalogued as COSV56711146; called by muse, mutect2, varscan2
- OR2A12 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV101283150, COSV68821183; called by muse, mutect2, varscan2
- SLC3A2 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1241619637, COSV58603123; called by muse, mutect2, varscan2
- TNFRSF21 | c.1897G>T p.G633* | Nonsense Mutation (SNP) | VAF 45/172 reads (26%) | catalogued as COSV57281024; called by muse, mutect2, varscan2
- TTLL8 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV56723961, COSV99838506; called by muse, mutect2
- ZNF568 | c.574_577del p.L192Dfs*7 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | catalogued as rs779015650; called by pindel, varscan2
- NT5DC3 | c.606_607del p.F202Lfs*30 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- SPATA31A1 | c.3974C>A p.P1325Q | Missense Mutation (SNP) | VAF 76/370 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FOXR2 | c.870T>G p.A290= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV59258090; called by muse, mutect2, varscan2
- HTR5A | c.822G>A p.T274= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs572459769, COSV55281779; called by muse, mutect2, varscan2
- SHANK1 | c.660G>A p.A220= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs775556161, COSV53246569; called by muse, mutect2, varscan2
